Gene-level copy-number profile of tumor specimen TCGA-2G-AAIG-01A from TCGA case TCGA-2G-AAIG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 35.6 years (13,012 days).
Specimen TCGA-2G-AAIG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68abd263-bcb9-4a45-9d06-dc2658cb27ca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAIG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/21047196-d9ae-4c8c-915e-e05957119303

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 631; copy number 2: 10,772; copy number 3: 26,917; copy number 4: 16,305; copy number 5: 874; copy number 6: 1,308; copy number 7: 2,103.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,103 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,022,247–62,275,678, 901 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:64,180,006–74,633,884, 219 genes, copy number 7 (broad region; genes not listed).
- chr7:75,899,200–84,492,724, 111 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–10,223,128, 366 genes, copy number 7 (broad region; genes not listed).
- chr21:13,038,160–39,929,397, 506 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
